Somatic mutation profile of tumor specimen TCGA-CG-5720-01A (aliquot TCGA-CG-5720-01A-11D-1600-08) from TCGA case TCGA-CG-5720, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,176 days).
Specimen TCGA-CG-5720-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6b5ed97-7348-4fab-9cff-d17467d0dbe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5720-11A (Solid Tissue Normal), aliquot TCGA-CG-5720-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd407f94-13d2-4b7b-91a3-16609f6328f1

The open-access MAF lists 83 somatic variants for this specimen: 57 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 51, Silent 26, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.125A>C p.Y42S | Missense Mutation (SNP) | VAF 73/263 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148189507, COSV63975769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR2A | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54027363; called by muse, mutect2
- ADAM21 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV50804430; called by muse, mutect2, varscan2
- ADGRV1 | c.7261C>A p.P2421T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV67981173, COSV67992934; called by muse, mutect2, varscan2
- AGBL5 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59937733; called by muse, mutect2
- APBA2 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs757921952, COSV67105500; called by muse, mutect2, varscan2
- ASXL3 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52475736; called by muse, mutect2, varscan2
- BHMT | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV57155431; called by muse, mutect2, varscan2
- BICC1 | c.2249A>C p.E750A | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV54065961; called by muse, mutect2, varscan2
- C12orf42 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs532571673, COSV59388763; called by muse, mutect2, varscan2
- C1S | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); catalogued as rs373197181; called by muse, mutect2, varscan2
- C8B | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs202207968; called by muse, mutect2, varscan2
- CACNA2D4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as rs555700156, COSV54957400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC14 | c.557A>G p.K186R (on ENST00000488653; = p.K138R on NM_022757.5) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV59947236; called by muse, mutect2, varscan2
- CD1C | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100939378, COSV63807289; called by muse, mutect2, varscan2
- CDKAL1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV51186053; called by muse, mutect2, varscan2
- CHD4 | c.3295T>C p.F1099L (on ENST00000357008 / NM_001363606.2; = p.F1112L on NM_001273.5) | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58894723; called by muse, mutect2, varscan2
- CRB1 | c.2849C>A p.A950E | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV66332598; called by muse, mutect2, varscan2
- CTNNA1 | c.2375T>A p.I792N | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57079607; called by muse, mutect2, varscan2
- DNAH5 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs748080642, COSV54201860; called by muse, mutect2, varscan2
- ELOVL5 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV58652557; called by muse, mutect2, varscan2
- FAT4 | c.11231C>A p.T3744K | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.23); catalogued as COSV58702420; called by muse, mutect2, varscan2
- FBN2 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039059, COSV52534451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO34 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV58256435; called by muse, mutect2, varscan2
- FES | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV61000300; called by muse, mutect2, varscan2
- GSTM3 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56662889; called by muse, mutect2, varscan2
- IGDCC4 | c.718A>T p.R240W | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV61538781; called by muse, mutect2, varscan2
- KMT2B | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55867018; called by muse, mutect2, varscan2
- MAN2B1 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as rs759767616, COSV55471287; called by muse, mutect2, varscan2
- MAP2K4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV62259747; called by muse, mutect2, varscan2
- MSR1 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.655); catalogued as COSV50525842; called by muse, mutect2, varscan2
- MYT1L | c.3189C>G p.I1063M | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV67704225; called by muse, mutect2
- PCDH15 | c.4660C>A p.P1554T | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV57257225, COSV57372132; called by muse, mutect2, varscan2
- PFKFB3 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 77/226 reads (34%) | PolyPhen probably damaging (0.96); catalogued as rs747166742, COSV57992172; called by muse, mutect2, varscan2
- PGBD1 | c.588A>C p.E196D | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV52555504; called by muse, mutect2, varscan2
- PRTG | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66839958; called by muse, mutect2
- PSG2 | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 123/581 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs377465339; called by muse, mutect2, varscan2
- RBBP7 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV66300815; called by muse, mutect2, varscan2
- RIMS1 | c.4486A>G p.S1496G | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53476490; called by muse, mutect2, varscan2
- RNF43 | c.1371C>A p.Y457* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as COSV68457955; called by muse, mutect2, varscan2
- RNPEPL1 | c.1794C>G p.N598K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54373619; called by muse, mutect2, varscan2
- ROBO1 | c.3481G>T p.G1161W | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71397457; called by muse, mutect2, varscan2
- RYR3 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV66804475; called by muse, mutect2, varscan2
- SALL1 | c.2470T>G p.F824V | Missense Mutation (SNP) | VAF 101/356 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as COSV51762732; called by muse, mutect2, varscan2
- SCN5A | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs199473160, CM097844, COSV61137106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPESP1 | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV52994238; called by muse, mutect2, varscan2
- SV2A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 56/139 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV64965591; called by muse, mutect2, varscan2
- TENM3 | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs200031135; called by muse, mutect2, varscan2
- TLE4 | c.521G>C p.S174T | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV54639067; called by muse, mutect2, varscan2
- USP48 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as COSV57613298; called by muse, mutect2, varscan2
- VRK3 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57467341; called by muse, mutect2
- WDR6 | c.2493T>A p.H831Q | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58246883; called by muse, mutect2, varscan2
- ZNF584 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.957); catalogued as rs368251865; called by muse, mutect2
- C4orf50 | c.256del p.R86Gfs*6 (on ENST00000324058; = p.R1318Gfs*6 on NM_001364689.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- KRT8 | c.300_302del p.N100del | In Frame Del (DEL) | VAF 32/121 reads (26%) | called by pindel, varscan2
- PIGR | c.1973_1974dup p.G659Wfs*172 | Frame Shift Ins (INS) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- ANK2 | c.8139C>T p.V2713= | Silent (SNP) | VAF 59/190 reads (31%) | catalogued as rs564510599, COSV52174749; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP25 | c.1848C>T p.R616= (on ENST00000409202 / NM_001007231.3; = p.R608= on NM_014882.3) | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as rs760572594, COSV54906670; called by muse, mutect2, varscan2
- ASXL1 | c.2484C>T p.G828= | Silent (SNP) | VAF 86/303 reads (28%) | catalogued as COSV60117733; called by muse, mutect2, varscan2
- BPTF | c.3012A>G p.Q1004= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV58844297; called by muse, mutect2, varscan2
- BRCA2 | c.3738T>C p.N1246= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV66460056; called by muse, mutect2, varscan2
- C1GALT1C1 | c.429A>G p.A143= | Silent (SNP) | VAF 92/136 reads (68%) | catalogued as rs1569408745, COSV58974634; called by muse, mutect2, varscan2
- C6orf118 | c.960G>A p.A320= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs761856449, COSV57813337; called by muse, mutect2, varscan2
- CARMIL2 | c.3613C>T p.L1205= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as rs1321307594, COSV54669693; called by muse, mutect2, varscan2
- CEACAM4 | c.507C>T p.A169= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV55732781, COSV99701241; called by muse, mutect2, varscan2
- COL17A1 | c.510G>A p.S170= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs762634230, COSV62227789; called by muse, mutect2, varscan2
- DSCAML1 | c.5736C>T p.A1912= (on ENST00000321322; = p.A1852= on NM_020693.4) | Silent (SNP) | VAF 100/362 reads (28%) | catalogued as rs760918261, COSV58400014; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFL1 | c.747C>T p.A249= | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as rs1327995758, COSV51608911; called by muse, mutect2, varscan2
- EPB41L2 | c.906T>G p.S302= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV61358033; called by muse, mutect2, varscan2
- FOXO1 | c.1218G>A p.S406= | Silent (SNP) | VAF 72/230 reads (31%) | catalogued as rs1300857603, COSV65428015; called by muse, mutect2, varscan2
- KLK8 | c.141G>A p.Q47= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV51593952; called by muse, mutect2, varscan2
- MAST1 | c.1269C>T p.R423= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs759623718, COSV52245041, COSV52252512; called by muse, mutect2, varscan2
- METTL4 | c.1144C>T p.L382= | Silent (SNP) | VAF 70/195 reads (36%) | catalogued as COSV60604522; called by muse, mutect2, varscan2
- MTMR4 | c.3450G>A p.L1150= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV60202663; called by muse, mutect2, varscan2
- NCL | c.480C>T p.D160= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs1411408902, COSV59547107; called by muse, mutect2, varscan2
- OOEP | c.21C>T p.A7= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs1311843760, COSV64859484; called by muse, mutect2, varscan2
- OR1C1 | c.123G>T p.G41= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV68715748, COSV68716204; called by muse, mutect2, varscan2
- PCARE | c.1350G>T p.L450= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV59056958; called by muse, mutect2
- PCDH11Y | c.162C>T p.G54= (on ENST00000400457 / NM_032973.2; = p.G43= on NM_032971.3) | Silent (SNP) | VAF 53/83 reads (64%) | catalogued as rs1193907765, COSV53088594; called by muse, mutect2, varscan2
- PCDHB5 | c.2109G>A p.S703= | Silent (SNP) | VAF 63/200 reads (32%) | catalogued as rs1326631392, COSV50647444; called by muse, mutect2, varscan2
- RBL1 | c.1680A>G p.E560= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as rs1237422442, COSV60332703; called by muse, mutect2
- YJU2 | c.36G>A p.P12= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs368087162, COSV53607462; called by muse, mutect2, varscan2
